Somatic mutation profile of tumor specimen TARGET-20-PATCLR-09A (aliquot TARGET-20-PATCLR-09A-01D) from TARGET case TARGET-20-PATCLR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 19.0 years (6,952 days).
Specimen TARGET-20-PATCLR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cde7a74-f45c-42df-9f70-cc9c3a801a68.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATCLR-14A (Bone Marrow Normal), aliquot TARGET-20-PATCLR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b5a2458-abda-4dd2-9075-b4b71ee029a4

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 39/93 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMC3 | c.3352G>A p.G1118R | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397305026; called by muse, mutect2, varscan2
- ERF | c.879dup p.P294Afs*15 | Frame Shift Ins (INS) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
- CBFB | c.400-9T>G | Intron (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
